Surgical pathology report (de-identified scan), TCGA case TCGA-JV-A5VF, project TCGA-SARC (Sarcoma), tissue source site BLN - Baylor, specimen TCGA-JV-A5VF-01A (Primary Tumor).

[page 1 of 3]
Go to...

Report for (MRN:)

TEST: SURG PATH

Result Name	Results	Units	Reference Range
SURGICAL	SURGICAL PATHOLOGY		
	(..)		

SURGICAL PATHOLOGY REPORT

Final

Date of Service

Status: Signed Out

MICROSCOPIC DIAGNOSIS:

PELVIC MASS, BIOPSY:

LEIOMYOSARCOMA, SEE BELOW

UTERUS, BILATERAL ADNEXA, RIGHT COLON AND DISTAL ILEUM, HYSTERECTOMY AND COLECTOMY:

UTERINE LEIOMYOSARCOMA ASSOCIATED WITH TUMOR DEPOSITS IN OMENTUM, PERIADNEXAL SOFT TISSUE AND PERI-ENTERIC SOFT TISSUE, SEE BELOW

NO INVASION INTO THE COLON, APPENDIX, OR ILEUM IS IDENTIFIED

CUL-DE-SAC MASS AND CERVIX, EXCISION:

LEIOMYOSARCOMA, SEE BELOW

CHRONIC CERVICITIS

SIGMOID EPIPLOICA, EXCISION:

LEIOMYOSARCOMA INVOLVING FIBROADIPOSE TISSUE, SEE BELOW

MESENTERIC NODULE, EXCISION:

LEIOMYOSARCOMA, SEE BELOW

OMENTUM, EXCISION:

LEIOMYOSARCOMA INVOLVING FIBROADIPOSE TISSUE, SEE BELOW

Tumor Site: Gynecologic

Tumor Size: 16 cm greatest dimension

Histologic Type: Leiomyosarcoma, poorly differentiated/epithelioid

Mitotic Rate: 56/10 hpf's

Necrosis: Present (33%)

Histologic Grade: FNCLCC grade 3

Margins: Cannot be assessed

Pathologic Staging: T2b NX MX

Ancillary Studies:

The tumor is positive for SMA and desmin.

Pathologist

88331 X2; 88332 X 2; 88309; 88305 x4, 88342 X 2

CLINICAL HISTORY:

Pelvic mass

SPECIMEN SOURCE:

Biopsy of pelvic mass; uterine fundus, bilateral adnexa, right colon, appendix and distal ileum; cul-de-sac mass and cervix; sigmoid epiploica; mesenteric nodule; omentum

GROSS DESCRIPTION:

FROZEN SECTION DIAGNOSIS, PELVIC MASS, BIOPSY: MALIGNANT TUMOR, DEFER TO PERMANENT SECTIONS (A1FS)

Specimen 1 is received fresh for intraoperative consultation in a container labeled with the patient's name, medical record number and "biopsy of pelvic mass" and consists of irregular fragment of friable tan tissue (2.0 x 1.5 x 1.0 cm) admixed with blood clot. Representative sections are

ICD-O-3
Leiomyosarcoma A165
8892/3
Site Path
Fundus Uteri 054.3
OUF Uterus NOS 055.9
Q40 4/4/13

[page 2 of 3]
submitted for frozen section in cassette A1FS and the remainder of the specimen is submitted in cassette A2 and A3.

FROZEN SECTION DIAGNOSIS, PELVIC MASS: SPINDLE CELL NEOPLASM, FAVOR LEIOMYOSARCOMA

Specimen 2 is received fresh for intraoperative consultation labeled "uterine fundus, bilateral adnexa, right colon, appendix, and distal ileum." The specimen consists of a uterus (6.0 x 5.0 x 4.0 cm) with cervix remnant (2.0 x 1.2 cm in surface diameter, excised to a depth of 1.1 cm), attached bilateral ovaries (2.2 x 1.2 x 0.5 cm each), bilateral fallopian tubes (8.0 cm in length and 0.3 cm in diameter each), with adhered distal ileum (45.2 cm in length), appendix (6.0 cm in length and 0.3 cm in diameter), and attached colon (6.0 cm in length and 4.0 cm in circumferential diameter) and mesenteric fat (approximately 20.0 cm). There is an ill-defined tan, friable mass (approximately 16.0 x 16.0 x 12.0 cm) that extends from the uterine fundus through the serosa and invades the surrounding soft tissue. The tumor is adherent to the colon, ileum and appendix without invasion into these structures. The mass has mottled, friable tan cut surfaces with extensive hemorrhage and necrosis. Multiple tumor nodules involving the bowel wall, mesentery, external surface of the right fallopian tube are identified.

The endometrial cavity measures 4.0 x 3.0 cm and is lined by pink-tan endometrium, 0.2 cm in average thickness. The posterior endometrium shows an endometrial polyp (3.0 x 1.2 x 0.3 cm). The myometrium is pink-tan with an average thickness of 2.5 cm. The myometrium shows multiple intramural and subserosal white-tan, firm nodules (1.0 to 7.0 cm in greatest dimension) with whorled cut surfaces. No hemorrhage, necrosis, or degeneration is seen. The ovaries and fallopian tubes are grossly unremarkable.

The colonic mucosa is grossly normal. The serosa shows multiple tumor deposits. The attached mesenteric fat has numerous tumor deposits.

Section code:

B1 and B2FS representative sections of the mass in relation to the myometrium;

B3FS, representative section of the tumor in relation to the bowel wall;

B4 and B5, endometrial polyp, entirely submitted;

B6, anterior cervix; B7, posterior cervix;

B8 and B9, anterior endomyometrium; B10 and B11, posterior endomyometrium;

B12-B15, representative sections of the intramural white nodule;

B16, representative section of the right ovary;

B17 and B18, representative sections of the right fallopian tube with possible attached tumor nodule;

B19, representative section of the left ovary;

B20, representative cross sections of the left fallopian tubes;

B21-B29, representative section of the tumor;

B30, ileal margin; B31, colon margin;

B32 and B33, B34, representative sections of tumor and bowel;

B35, representative section of the tip of appendix with the tumor;

B36, representative cross section of appendix with the tumor;

B37-B40, representative sections of the mesenteric nodules.

Specimen 3, received fresh labeled with the patient's name, medical record number, and "cul-de-sac mass and cervix," consists of a portion of ectocervix that measures 2.6 x 2.1 cm in diameter and covered by pink-tan exocervical mucosa and 0.1 cm slitlike os with attached irregular fragment of soft tissue that is extensively involved by tumor measures 8.0 x 6.0 x 1.5 cm.

Section code: C1, anterior cervix; C2, posterior cervix; C3-C5, representative section of attached soft tissue with the mass.

Specimen 4, received fresh labeled with the patient's name, medical record number, and "sigmoid epiploica," consists of irregular fragments of fibroadipose tissue measuring 2.1 x 1.9 x 0.5 cm. The specimen is serially

[page 3 of 3]
sectioned to reveal fibrofatty cut surfaces with no grossly identifiable nodule. The specimen is entirely submitted in cassettes D1-D5. Specimen 5, received with formalin in a container labeled with the patient's name, medical record number, and "mesenteric nodule," consists of an irregular fragment of pink-tan, friable soft tissue measuring 1.5 x 1.4 x 1.2 cm. The specimen is entirely submitted in cassettes E1 and E2. Specimen 6, received with formalin in a container labeled with the patient's name, medical record number, and "omentum," consists of a flat sheet of fibroadipose tissue measuring 16.0 x 3.0 x 0.6 cm. There are multiple pink-tan friable tumor nodules identified. Representative section of the nodule is submitted in cassettes F1-F4.

The following special studies were performed on this case and the interpretation is incorporated in the diagnostic report above:

1xACTIN SMOOTH MUSCLE, 1xDESMIN

The immunohistochemistry test was developed and its performance characteristics determined by Pathology Laboratory. It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. The test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing. Performed at:

--Electronically Signed Out by

Source: NCI Genomic Data Commons file 2c52e106-17b7-4554-a6de-ab0709b3205d (TCGA-JV-A5VF.BA983F27-4220-42EF-8BF4-F2D6CDBB5BA6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).